Gene-level copy-number profile of tumor specimen TCGA-37-4129-01A from TCGA case TCGA-37-4129, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.4 years (19,154 days).
Specimen TCGA-37-4129-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ac4429db-9645-465b-89e0-b2afbb27c876.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-4129-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd6ccbd5-6507-44dc-ace9-9769ffd2944a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,542; copy number 2: 52,278.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-4129-01A-01D-1969-01): tumor purity 0.45, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
